Somatic mutation profile of tumor specimen TARGET-10-PARUYE-03A (aliquot TARGET-10-PARUYE-03A-01D) from TARGET case TARGET-10-PARUYE, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.7 years (616 days).
Specimen TARGET-10-PARUYE-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ccd3e2e-6a1e-451c-85c3-09aaa9bdf97f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARUYE-10A (Blood Derived Normal), aliquot TARGET-10-PARUYE-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f7d0d355-66c2-4284-884e-4b7fab5db85f

The open-access MAF lists 9 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 3, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2503G>C p.D835H | Missense Mutation (SNP) | VAF 27/66 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913488, COSV54042116, COSV54042636, COSV54045151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DCDC1 | c.2057G>T p.S686I | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs373385665; called by muse, mutect2, varscan2
- ERG | c.1109A>C p.D370A (on ENST00000398919 / NM_001243428.1; = p.D346A on NM_004449.4) | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55729043; called by muse, mutect2, varscan2
- TRPM3 | c.1773G>C p.K591N (on ENST00000357533 / NM_001366142.2; = p.K424N on NM_020952.6) | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- ASCC2 | c.864C>T p.P288= | Silent (SNP) | VAF 35/94 reads (37%) | catalogued as rs373593377; called by muse, mutect2, varscan2
- CACNA1F | c.1611G>A p.L537= | Silent (SNP) | VAF 34/80 reads (43%) | called by muse, mutect2, varscan2
- TRGJP1 | c.51A>G p.V17= | Silent (SNP) | VAF 30/80 reads (38%) | catalogued as rs758711882; called by muse, mutect2, varscan2
- AP5Z1 | c.*23G>A | 3'UTR (SNP) | VAF 5/10 reads (50%) | catalogued as rs568094732; called by muse, varscan2
- ZFP69 | c.*83G>T | 3'UTR (SNP) | VAF 8/15 reads (53%) | called by muse, mutect2, varscan2
